Somatic mutation profile of tumor specimen RC-B55A-TTP1-A (aliquot RC-B55A-TTP1-A-1-1-D-A93N-47) from RC case RC-B55A, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Dead; Primary diagnosis: Peripheral T-cell lymphoma, NOS; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 57.2 years (20,882 days).
Specimen RC-B55A-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 097b596e-d87d-4308-950c-cec7b077f0b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B55A-NM1-A (Bone Marrow Components NOS; tissue type Normal), aliquot RC-B55A-NM1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44cf73b7-35f7-4fe6-a297-8230ed1bc9d0

The open-access MAF lists 25 somatic variants for this specimen: 15 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 8, Intron 1, Nonsense Mutation 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD50 | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as rs766970033; called by muse, mutect2, varscan2
- CDH9 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.101); catalogued as rs780851499, COSV50260752; called by muse, mutect2, varscan2
- COL13A1 | c.947G>A p.R316Q (on ENST00000398978 / NM_001130103.2; = p.R259Q on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.913); catalogued as rs369087232; called by muse, mutect2, varscan2
- CXCR1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as rs147031882; called by muse, mutect2, varscan2
- FRS3 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs768943329; called by muse, mutect2, varscan2
- MUC12 | c.12938C>T p.T4313M (on ENST00000379442; = p.T4170M on NM_001164462.1) | Missense Mutation (SNP) | VAF 44/352 reads (13%) | SIFT tolerated (0.14); catalogued as rs756211697, COSV65211488; called by muse, varscan2
- MUC6 | c.5267C>T p.T1756I | Missense Mutation (SNP) | VAF 74/943 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); catalogued as rs759089228; called by muse, mutect2
- PCK1 | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs746384406; called by muse, mutect2, varscan2
- TENM3 | c.4432G>A p.A1478T | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as COSV69311728; called by muse, mutect2, varscan2
- WHRN | c.2453G>A p.R818H | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs762248099; called by muse, varscan2
- ADAMTS5 | c.1276T>A p.C426S | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCC1 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2, varscan2
- SDR42E2 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SH3KBP1 | c.374T>C p.I125T | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, varscan2
- ZNF280B | c.1495del p.T499Qfs*19 | Frame Shift Del (DEL) | VAF 31/204 reads (15%) | called by mutect2, pindel, varscan2
- COL20A1 | c.2073C>T p.H691= | Silent (SNP) | VAF 26/115 reads (23%) | catalogued as rs1164295610, COSV100490792, COSV58924311; called by muse, mutect2, varscan2
- DGKB | c.1680C>T p.D560= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as rs1349700066; called by muse, mutect2
- PNPLA1 | c.555C>T p.T185= (on ENST00000394571 / NM_001374623.1; = p.T90= on NM_173676.2) | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as rs748310345, COSV100463867; called by muse, mutect2, varscan2
- SPATS2 | c.729A>G p.K243= | Silent (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- STIM1 | c.129C>A p.S43= | Silent (SNP) | VAF 30/155 reads (19%) | called by muse, varscan2
- TADA1 | c.657G>A p.K219= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as rs775491342; called by mutect2, varscan2
- TBC1D7 | c.591G>T p.A197= | Silent (SNP) | VAF 35/172 reads (20%) | catalogued as COSV58245519; called by muse, mutect2, varscan2
- TMEM63B | c.1464G>A p.S488= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as rs755947120; called by muse, mutect2, varscan2
- C2CD6 | c.1581+3038G>C | Intron (SNP) | VAF 33/123 reads (27%) | called by muse, mutect2, varscan2
- SHISA8 | chr22:41909834 G>A | 3'Flank (SNP) | VAF 19/81 reads (23%) | catalogued as rs1242217612; called by muse, mutect2, varscan2
